HCMI case HCM-CSHL-0698-C06 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/a870c27c-b854-4c7e-81c3-9a3d66d4d778

Demographics
Sex at birth: female; Days to birth: -24,090 days (66.0 years before the index date); Year of birth: 1953; Vital status: Dead; Days to death: 416 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C06.9; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic stage: Stage II; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Lymph Node, Regional.
   Pathology details: Additional pathology findings: PD-L1 CPS (223C LDT) - 20%.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C77.0; Tissue or organ of origin: Head, face or neck, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 416 days (1.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 67.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 172 cm; BMI: 22.3.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-CSHL-0698-C06-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0698-C06-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
